TCGA case TCGA-14-0812 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Emory University. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/eff7f13b-ed32-4e85-a8d0-831b655d773f

Demographics
Sex at birth: male; Race: white; Age at index: 65 years; Vital status: Dead; Days to death: 99 days.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 65.9 years (24,085 days); Year of diagnosis: 2003; Method of diagnosis: Surgical Resection; Prior treatment: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carmustine Implant; Treatment intent type: Adjuvant; Days to treatment start: 0 days; Treatment dose: 8 Wafer.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Dexamethasone; Treatment intent type: Adjuvant; Days to treatment start: 0 days.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 99 days; Disease response: With Tumor.
- Karnofsky performance status: 40; Timepoint: Post Adjuvant Therapy.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-14-0812-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1; Intermediate dimension: 0.7; Shortest dimension: 0.3.
  Slide TCGA-14-0812-01B-01-BS1: Section location: Bottom; Percent tumor cells: 100; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0.
  Slide TCGA-14-0812-01B-01-TS1: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 0.
- Sample TCGA-14-0812-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection; Performance status timing: Post-Adjuvant Therapy.
- Drug treatment 2: Pharmaceutical therapy drug name: Gliadel Wafers.
- Drug treatment 2, Route of administrations: Route of administration: Other (specify below).

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 99 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 99 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 99 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-14-0812-01B-01D-0591-01): tumor purity 0.66, ploidy 1.92, whole-genome doublings 0.
